Gene-level copy-number profile of tumor specimen TCGA-VS-A9UP-01A from TCGA case TCGA-VS-A9UP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.4 years (15,849 days).
Specimen TCGA-VS-A9UP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e5b3c6a1-0f61-43c3-af2f-5e7fcbf051e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d69e9ff-9ff0-4b1c-8d4f-7cd5c0085000

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 652; copy number 2: 3,886; copy number 3: 9,397; copy number 4: 22,941; copy number 5: 7,275; copy number 6: 5,309; copy number 7: 6,607; copy number 8: 2,016; copy number 9: 853; copy number 10: 471; copy number 11: 144; copy number 12: 98; copy number 13: 15; copy number 25: 6; copy number 27: 52; copy number 35: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UP-01A-11D-A42N-01): tumor purity 0.43, ploidy 4.62, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,731 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,555,001–13,696,199, 5 genes, copy number 9: BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2.
- chr1:236,664,141–242,524,697, 87 genes, copy number 9 (broad region; genes not listed).
- chr2:81,194,337–85,102,694, 40 genes, copy number 9: ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, AC022210.1, KCMF1, LINC01964, AC078974.1, LSM3P3.
- chr3:143,620,528–170,454,733, 385 genes, copy number 9 (broad region; genes not listed).
- chr3:170,423,103–170,423,162, 1 gene, copy number 9: MIR6828.
- chr3:172,889,357–198,222,513, 507 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr5:32,174,471–41,510,628, 154 genes, copy number 9–12 (broad region; genes not listed).
- chr5:148,025,683–148,137,382, 1 gene, copy number 9 (within-gene range 5–9): SPINK5.
- chr11:101,451,564–103,479,863, 52 genes, copy number 27 (within-gene range 3–27): TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr12:116,482,073–119,303,380, 57 genes, copy number 10–13: LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5, AC026367.1, SUDS3, AC026367.3, AC026367.2, LINC02460, RPL17P37, LINC02423, LINC02440, LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4, AC087885.1, RN7SL508P, AC084361.1, HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934.
- chr13:31,419,989–31,483,699, 2 genes, copy number 11: AL161616.2, AL161616.1.
- chr14:21,941,128–22,490,553, 64 genes, copy number 10 (broad region; genes not listed).
- chr14:33,597,057–38,256,093, 98 genes, copy number 25–35 (broad region; genes not listed).
- chr16:69,565,094–77,299,950, 214 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr17:49,505,657–49,574,064, 1 gene, copy number 9 (within-gene range 7–9): AC006487.1.
- chr17:49,544,788–50,181,178, 31 genes, copy number 9 (within-gene range 5–9): AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P.
- chr20:31,341,371–31,723,989, 25 genes, copy number 11: HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:51,782,331–52,204,308, 7 genes, copy number 9: SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.

Autosomal genes at a single copy (total copy number 1): 652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
